Somatic mutation profile of tumor specimen 0DI3M2 from CCDI case PBBVIM, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: male; Primary diagnosis: Pilocytic astrocytoma; Tissue or organ of origin: Overlapping lesion of brain; Age at diagnosis: 7.4 years (2,685 days).
Specimen 0DI3M2: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) d41e795a-0f76-4042-b43a-b65e41ce38ef.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DI3JJ (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/45baaf17-4174-465d-8185-f44fea15d041

The open-access MAF lists 3 somatic variants for this specimen: 2 protein-altering or splice-affecting, 1 silent.
By variant classification: Missense Mutation 2, Silent 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HOOK1 | c.129G>T p.M43I | Missense Mutation (SNP) | VAF 193/980 reads (20%) | SIFT tolerated (0.99); PolyPhen benign (0.022); catalogued as COSV100969200; called by muse, mutect2, varscan2
- SLC22A1 | c.1067C>G p.T356R | Missense Mutation (SNP) | VAF 71/325 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (0.982); called by muse, mutect2, varscan2
- RETSAT | c.789C>T p.F263= | Silent (SNP) | VAF 20/621 reads (3%) | catalogued as COSV55526571; called by muse, mutect2
